Somatic mutation profile of tumor specimen TCGA-DD-AAED-01A (aliquot TCGA-DD-AAED-01A-12D-A40R-10) from TCGA case TCGA-DD-AAED, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 51.3 years (18,722 days).
Specimen TCGA-DD-AAED-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63b30062-a642-4e23-92f2-919aaae042cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AAED-10A (Blood Derived Normal), aliquot TCGA-DD-AAED-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bb490e0-7e35-42bc-ba57-c726a204b99b

The open-access MAF lists 79 somatic variants for this specimen: 56 protein-altering or splice-affecting, 23 silent.
By variant classification: Missense Mutation 48, Silent 23, Frame Shift Del 3, Nonsense Mutation 2, Splice Site 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.376-1G>A p.X126_splice | Splice Site (SNP) | VAF 34/42 reads (81%) | hotspot (GDC flag); catalogued as rs868137297, CS1313555, COSV52688618, COSV52749979, COSV52994579, COSV52996344; ClinVar: likely pathogenic / pathogenic / not provided; called by muse, mutect2, varscan2
- ABHD3 | c.555G>A p.L185= | Splice Region (SNP) | VAF 145/370 reads (39%) | catalogued as rs562863991, COSV100004281; called by muse, mutect2, varscan2
- ACOX2 | c.1394C>T p.T465M | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.23); catalogued as rs1317973851, COSV57147955; called by muse, mutect2, varscan2
- ADCY4 | c.802A>T p.R268W | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99353099; called by muse, varscan2
- ADCY4 | c.801G>T p.K267N | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.868); catalogued as COSV99353101; called by muse, varscan2
- ADGRG4 | c.2246C>A p.T749N | Missense Mutation (SNP) | VAF 221/241 reads (92%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.722); catalogued as COSV99795002; called by muse, mutect2, varscan2
- AFF1 | c.1859G>T p.S620I | Missense Mutation (SNP) | VAF 116/153 reads (76%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs972189811, COSV100320355; called by muse, mutect2, varscan2
- ATP1A2 | c.620A>G p.H207R | Missense Mutation (SNP) | VAF 35/116 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV100767722; called by muse, mutect2, varscan2
- ATP2C2 | c.1352C>T p.A451V | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV99297757; called by muse, mutect2, varscan2
- CACNA1E | c.2089G>T p.V697L | Missense Mutation (SNP) | VAF 48/94 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.049); catalogued as COSV100701768; called by muse, mutect2, varscan2
- CACNA2D1 | c.1228T>C p.Y410H | Missense Mutation (SNP) | VAF 303/705 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); catalogued as COSV100666341; called by muse, mutect2, varscan2
- CDYL | c.558C>A p.N186K (on ENST00000328908 / NM_001368125.1; = p.N132K on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.005); catalogued as COSV100189071; called by muse, mutect2, varscan2
- CTTNBP2 | c.2021C>T p.S674L | Missense Mutation (SNP) | VAF 78/184 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as COSV99353549; called by muse, mutect2, varscan2
- DEFB125 | c.58+1del | Frame Shift Del (DEL) | VAF 52/141 reads (37%) | catalogued as COSV66703299; called by mutect2, varscan2
- DOCK4 | c.1151C>A p.S384Y | Missense Mutation (SNP) | VAF 48/113 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as COSV101455487, COSV70323271; called by muse, mutect2, varscan2
- EPB41L4B | c.2024A>T p.K675M | Missense Mutation (SNP) | VAF 67/80 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.522); catalogued as COSV100775841; called by muse, mutect2, varscan2
- FCRL1 | c.452C>A p.A151D | Missense Mutation (SNP) | VAF 67/206 reads (33%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.882); catalogued as rs1172383985, COSV100839751; called by muse, mutect2, varscan2
- FURIN | c.1377A>T p.K459N | Missense Mutation (SNP) | VAF 40/101 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as COSV99184643; called by muse, mutect2, varscan2
- GALNT10 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.115); catalogued as rs762822794, COSV51720527; called by muse, mutect2, varscan2
- GPATCH4 | c.305A>G p.Y102C | Missense Mutation (SNP) | VAF 75/193 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV100576900; called by muse, mutect2, varscan2
- GPR137B | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 56/94 reads (60%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.912); catalogued as rs199613305, COSV100858353, COSV63991293; called by muse, mutect2, varscan2
- GPR148 | c.91G>A p.A31T | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV99998559; called by muse, mutect2, varscan2
- KIT | c.2540C>T p.T847M | Missense Mutation (SNP) | VAF 42/60 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs752695117, COSV55393062; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLHL7 | c.1417A>C p.N473H (on ENST00000339077 / NM_001031710.3; = p.N425H on NM_018846.5) | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.46); catalogued as COSV100177914; called by muse, mutect2, varscan2
- KMT2B | c.2927A>G p.Q976R | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.821); catalogued as rs1287498488, COSV99719228; called by muse, mutect2, varscan2
- LOXL1 | c.272G>A p.S91N | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99985255; called by muse, mutect2, varscan2
- MED13L | c.187T>A p.C63S | Missense Mutation (SNP) | VAF 85/207 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV99928386; called by muse, mutect2, varscan2
- MFSD9 | c.581A>G p.E194G | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as COSV99302015; called by muse, mutect2, varscan2
- MMACHC | c.770C>T p.P257L | Missense Mutation (SNP) | VAF 41/80 reads (51%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.046); catalogued as rs201601241; called by muse, mutect2, varscan2
- OCLN | c.1550A>G p.Y517C | Missense Mutation (SNP) | VAF 344/929 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775502641, COSV100783800; called by muse, mutect2, varscan2
- P2RY10 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 55/64 reads (86%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.897); catalogued as COSV99409060; called by muse, mutect2, varscan2
- PCLO | c.1490C>T p.A497V | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.114); catalogued as rs1270435100, COSV100430042; called by muse, mutect2, varscan2
- PRMT7 | c.194A>G p.K65R | Missense Mutation (SNP) | VAF 74/103 reads (72%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as COSV100266849; called by muse, mutect2, varscan2
- PXDN | c.1437C>A p.H479Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV53244995, COSV99412951; called by muse, mutect2, varscan2
- RASA1 | c.1482T>G p.Y494* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as COSV99169701; called by muse, mutect2, varscan2
- RFC2 | c.664A>G p.I222V (on ENST00000055077 / NM_181471.3; = p.I188V on NM_002914.4) | Missense Mutation (SNP) | VAF 37/101 reads (37%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV99277825; called by muse, mutect2, varscan2
- RGL2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 184/389 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.062); catalogued as COSV101442493; called by muse, mutect2, varscan2
- RP1 | c.2897A>C p.N966T | Missense Mutation (SNP) | VAF 77/254 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as rs200109948, COSV99606920; called by muse, mutect2, varscan2
- SLC12A5 | c.923+1G>C p.X308_splice (on ENST00000454036 / NM_001134771.2; = p.X285_splice on NM_020708.5) | Splice Site (SNP) | VAF 29/70 reads (41%) | catalogued as COSV99715688; called by muse, mutect2, varscan2
- SLC17A2 | c.382A>C p.I128L | Missense Mutation (SNP) | VAF 79/183 reads (43%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV99614095; called by muse, mutect2, varscan2
- SLC22A11 | c.835T>A p.S279T | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100102245; called by muse, mutect2, varscan2
- SLITRK2 | c.1366T>A p.Y456N | Missense Mutation (SNP) | VAF 81/92 reads (88%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.677); catalogued as COSV100157541; called by muse, mutect2, varscan2
- SREBF1 | c.2005G>A p.A669T | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs946562068, COSV55418042; called by muse, mutect2, varscan2
- TBX2 | c.1975C>G p.L659V | Missense Mutation (SNP) | VAF 58/158 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV99538758; called by muse, mutect2, varscan2
- TENT2 | c.710A>G p.H237R | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99706358; called by muse, mutect2, varscan2
- TLL1 | c.2107T>C p.S703P | Missense Mutation (SNP) | VAF 77/96 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99286765, COSV99287016; called by muse, mutect2, varscan2
- TRPM6 | c.531A>C p.E177D | Missense Mutation (SNP) | VAF 46/64 reads (72%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as COSV100666043; called by muse, mutect2, varscan2
- UBQLNL | c.41G>C p.S14T | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.154); catalogued as COSV100974191; called by muse, mutect2, varscan2
- VEPH1 | c.2161G>T p.G721* | Nonsense Mutation (SNP) | VAF 52/132 reads (39%) | catalogued as COSV100747475; called by muse, mutect2
- ZC3H18 | c.1548G>T p.K516N | Missense Mutation (SNP) | VAF 102/123 reads (83%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.301); catalogued as COSV99963975; called by muse, mutect2, varscan2
- ZHX2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.311); catalogued as COSV100072811, COSV58715672; called by muse, mutect2, varscan2
- ZNF518A | c.3777A>C p.K1259N | Missense Mutation (SNP) | VAF 61/158 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.879); catalogued as COSV100283446; called by muse, mutect2, varscan2
- ZNF813 | c.788G>T p.R263I | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as COSV101124751; called by muse, mutect2, varscan2
- AWAT2 | c.112del p.Y38Tfs*36 | Frame Shift Del (DEL) | VAF 182/290 reads (63%) | called by mutect2, pindel, varscan2
- GDF2 | c.871G>T p.G291C | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- PLCH1 | c.357del p.W119* (on ENST00000340059 / NM_001130960.2; = p.W131* on NM_014996.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 53/142 reads (37%) | called by mutect2, pindel, varscan2
- ADAMTS6 | c.1989T>G p.T663= | Silent (SNP) | VAF 80/179 reads (45%) | called by muse, mutect2, varscan2
- ADGRA2 | c.3681C>T p.T1227= | Silent (SNP) | VAF 18/20 reads (90%) | catalogued as COSV99604836; called by muse, mutect2
- ALPP | c.34C>T p.L12= | Silent (SNP) | VAF 29/74 reads (39%) | catalogued as COSV101235123; called by muse, varscan2
- ATP11B | c.2352C>T p.C784= | Silent (SNP) | VAF 136/329 reads (41%) | catalogued as COSV100017659; called by muse, mutect2, varscan2
- BTBD1 | c.1416T>C p.D472= | Silent (SNP) | VAF 119/298 reads (40%) | catalogued as COSV99915369; called by muse, mutect2, varscan2
- CMYA5 | c.6471A>G p.T2157= | Silent (SNP) | VAF 114/289 reads (39%) | catalogued as rs777655259, COSV101483968; called by muse, mutect2, varscan2
- CPQ | c.252A>G p.L84= | Silent (SNP) | VAF 94/298 reads (32%) | catalogued as COSV99611318; called by muse, mutect2, varscan2
- ICE1 | c.2943G>A p.G981= | Silent (SNP) | VAF 50/100 reads (50%) | catalogued as rs777719226, COSV99664281; called by muse, mutect2, varscan2
- KCNC2 | c.387G>T p.V129= | Silent (SNP) | VAF 208/484 reads (43%) | catalogued as rs1010822722, COSV100128536; called by muse, mutect2, varscan2
- MAP1S | c.1485C>T p.G495= | Silent (SNP) | VAF 62/136 reads (46%) | catalogued as COSV100140957; called by muse, mutect2, varscan2
- MMP20 | c.915G>A p.V305= | Silent (SNP) | VAF 32/155 reads (21%) | catalogued as COSV99497566; called by muse, mutect2, varscan2
- OR8D4 | c.132C>T p.S44= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV58431893; called by muse, mutect2, varscan2
- PNLIPRP3 | c.915A>G p.T305= | Silent (SNP) | VAF 41/89 reads (46%) | catalogued as COSV100982437; called by muse, mutect2, varscan2
- SLC39A6 | c.1074G>T p.L358= | Silent (SNP) | VAF 98/195 reads (50%) | catalogued as COSV99309493; called by muse, mutect2, varscan2
- SNU13 | c.199C>T p.L67= | Silent (SNP) | VAF 64/100 reads (64%) | catalogued as COSV99316771; called by muse, mutect2, varscan2
- SPANXN1 | c.108C>A p.P36= | Silent (SNP) | VAF 212/248 reads (85%) | catalogued as COSV100979327, COSV65122143; called by muse, varscan2
- TMEM121B | c.663C>T p.A221= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs768757723, COSV100082985, COSV100083122; called by mutect2, varscan2
- TRIP13 | c.684G>A p.L228= | Silent (SNP) | VAF 28/137 reads (20%) | catalogued as COSV99386280; called by muse, mutect2, varscan2
- TRMT9B | c.399C>A p.P133= | Silent (SNP) | VAF 76/102 reads (75%) | catalogued as COSV101501541; called by muse, varscan2
- USH2A | c.9264A>G p.E3088= | Silent (SNP) | VAF 61/199 reads (31%) | catalogued as COSV100232289, COSV100232562, COSV100237869; called by muse, mutect2, varscan2
- ZFR | c.477A>G p.Q159= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs765409303, COSV99415619; called by muse, mutect2, varscan2
- ZNF536 | c.3627G>A p.L1209= | Silent (SNP) | VAF 53/109 reads (49%) | catalogued as COSV100834968; called by muse, mutect2, varscan2
- ZSWIM4 | c.744C>A p.I248= | Silent (SNP) | VAF 59/131 reads (45%) | catalogued as rs756132622, COSV99584681; called by muse, mutect2, varscan2
